Surgical pathology report (de-identified scan), TCGA case TCGA-DK-A3IU, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-A3IU-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB: (Age:

Gender: M

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

INPATIENT

Clinical Diagnosis & History:

year old male with recurrent high grade T1 urothelial carcinoma.

Specimens Submitted:

- 1: Urethral margin (fs)
- 2: Right distal pelvic lymph node
- 3: Left distal pelvic lymph node
- 4: Bladder, prostate, seminal vesicles and perivesicle lymph nodes; cystoprostatectomy
- 5: Left distal ureter
- 6: Right distal ureter

DIAGNOSIS:

1. Urethral margin; excision:
- Benign urethra and prostate tissue.

ICD-O-3
carcinoma, urothelial, NOS 8120/3
Site: bladder, wall, posterior c67.4
fw 12/7/11

2. Right distal pelvic lymph node:
Lymph Node Dissection:
Benign lymph nodes
Number of lymph nodes examined: 11

3. Left distal pelvic lymph node:
Lymph Node Dissection:
Benign lymph nodes
Number of lymph nodes examined: 3

4. Bladder, prostate, seminal vesicles and perivesicle lymph nodes; cystoprostatectomy:

Tumor Type:
Invasive urothelial carcinoma, NOS

Histologic Grade:
High grade

Pattern of growth of the Non-Invasive component:
In situ component not identified

Pattern of growth of the Invasive component:
Infiltrating

Tumor Multicentricity:
Not identified

Diagnostic Discrepancy		

[page 2 of 6]
SURGICAL PATHOLOGY REPORT

Bladder Local Invasion:

Deep half of muscularis propria

Extravesical Tumor Extension:

Ureters uninvolved

Urethra uninvolved

Vascular Invasion:

Identified

Perineural Invasion:

Identified

Surgical Margins:

Free of tumor

Non-Neoplastic Mucosa:

Exhibiting ulceration

Exhibiting foreign body reaction

Prostate:

Other See section b

Seminal Vesicles:

Not involved

Perivesical Lymph Nodes:

LN Not involved 1

The Pathologic Stage is (AJCC 2002):

pT2b (Invades deep half of muscularis propria)

PR0 (No involvement of prostate)

b.

Tumor Type:

Adenocarcinoma
of prostate

Gleason's Grade:

Primary Gleason grade:3

Secondary Gleason grade:3

Total Gleason score:6

Tumor Location:

Involves Right posterior

Involves Left posterior

Involves Left anterior

Dominant tumor mass located in: left anterior and posterior mid

Vascular Invasion:

Not Identified

Perineural Invasion:

Identified

Tumor Multicentricity:

Multicentric foci of invasive carcinoma are present

High Grade Prostatic Intraepithelial Neoplasia:

Identified

Capsule:

Tumor invades into, but not beyond prostate capsule

Seminal Vesicles:

[page 3 of 6]
SURGICAL PATHOLOGY REPORT

Not involved

Bladder Neck:

Not Involved

Surgical Margins:

Free of tumor

Non-Neoplastic Prostate:

Exhibits nodular hyperplasia

Staging (AJCC 1997):

pT2b (confined to the prostate & capsule, involving both lobes)

5. Left distal ureter; excision:

- Benign ureter.

6. Right distal ureter; excision:

- Benign ureter.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	RECUT	
	RECUT	
	RECUT	

Gross Description:

1. The specimen is received fresh, labeled "Urethral margin", and consists of one piece of tan soft tissue measuring 2.0 x 0.8 x 0.3 cm. The specimen is entirely submitted for frozen section diagnosis.

Summary of sections:

FSC -- frozen section control

2. The specimen is received in formalin, labeled "right distal pelvic lymph node", and consists of a piece of adipose tissue. The specimen is dissected to reveal multiple pink tan firm lymph nodes ranging from 0.3 x 0.3 x 0.3 cm to 4.1 x 0.6 x 0.5 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

BLN -- bisected lymph nodes

LN1 -- lymph nodes

LN2 -- largest lymph node, serially sectioned

[page 4 of 6]
SURGICAL PATHOLOGY REPORT

3. The specimen is received in formalin, labeled "left distal pelvic lymph node", and consists of portion of adipose tissue. The specimen is dissected to reveal multiple pink tan firm lymph nodes ranging from 0.5 x 0.3 x 0.3 cm to 4.2 x 0.6 x 0.5 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

BLN -- bisected lymph node
LN1 -- one lymph node, serially sectioned
LN2 -- largest lymph node, serially sectioned

4. The specimen is received fresh, labeled "bladder, prostate, seminal vesicles and perivesical lymph nodes". It consists of a bladder and prostate measuring 18.4 cm from superior to inferior, 15.0 cm laterally, and 4.6 cm from anterior to posterior. The bladder measures 5.5 x 3.5 x 3.2 cm, the prostate measure 3.2 x 3.6 x 3.0 cm, the right seminal vesicle measures 4.1 x 1.6 x 1.1 cm, the right vas deferens measures 3.1 cm in length and 0.3 cm in diameter, the left seminal vesicle measures 3.1 x 1.6 x 0.7 cm, and the left vas deferens measures 4.7 cm in length and 0.3 cm in diameter. The anterior aspect of the bladder is inked black and the posterior blue. The right lobe of the prostate is inked green; the left is inked black. The prostatic urethral margin is shaved and submitted. The bladder is opened along the anterior midline to reveal a tan firm tumor measuring 2.0 x 1.1 cm which is grossly situated within the posterior wall of the bladder. The lesion lies 1.2 cm from the left ureteral orifice and 1.1 cm from the right ureteral orifice. Both ureters are probe patent and measure up to 0.2 cm in maximum diameter. The lesion is sectioned to reveal the tumor invading the bladder wall. Extension to the inked fat is grossly not identified. The remaining bladder mucosa is pink-red congested and focally hemorrhagic. No perivesical lymph nodes are identified. The prostate is serially sectioned to reveal pink tan parenchyma. Representative sections are submitted including sections from each prostatic quadrant and transition zone. Tissue is submitted for

Summary of sections:

UTHM -- urethral margin
RUM -- right ureter margin
LUM -- left ureter margin
L -- lesion
RUO -- right ureter orifice
LUO -- left ureter orifice
LP -- left posterior wall
LA -- left anterior wall
RP -- right posterior wall
RA -- right anterior wall
TRI -- trigone
DOM -- dome
F -- perivesical fat
RSV -- right seminal vesicle
LSV -- left seminal vesicle
RAP -- right apex prostate
LAP -- left apex prostate
RAM -- right anterior mid prostate
RPM -- right posterior mid prostate
LAM -- left anterior mid prostate
LPM -- left posterior mid prostate
RAB -- right anterior base prostate
RPB -- right posterior base prostate
LAB -- left anterior base prostate
LPB -- left posterior base prostate
ADD -- additional sections of prostate

5. The specimen is received in formalin, labeled "left distal ureter large unclipped end margin", and consists of a 1.3 cm segment of ureter. The specimen is entirely submitted.

Summary of sections:

M -- margin
U -- remainder of ureter

[page 5 of 6]
SURGICAL PATHOLOGY REPORT

6. The specimen is received in formalin, labeled "right distal ureter large unclipped end margin", and consists of a 1.3 cm segment of ureter. The specimen is entirely submitted.

Summary of sections:

M -- margin

U -- remainder of ureter

Summary of Sections:

Part 1: Urethral margin (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 2: Right distal pelvic lymph node

Block	Sect. Site	PCs
2	BLN	2
2	LN1	3
2	LN2	3

Part 3: Left distal pelvic lymph node

Block	Sect. Site	PCs
1	BLN	2
1	LN1	2
2	LN2	3

Part 4: Bladder, prostate, seminal vesicles and perivesicle lymph nodes; cystoprostatectomy

Block	Sect. Site	PCs
7	ADD	7
1	DOM	2
1	F	2
5	L	7
1	LA	2
1	LAB	2
1	LAM	2
1	LAP	2
1	LP	2
1	LPB	2
1	LPM	2
1	LSV	2
1	LUM	2
1	LUO	2
1	RA	2
1	RAB	2
1	RAM	2
1	RAP	2
1	RP	2
1	RPB	2
1	RPM	2
1	RSV	2
1	RUM	2
1	RUO	2
1	TRI	2
1	UTHM	2

[page 6 of 6]
SURGICAL PATHOLOGY REPORT

Part 5: Left distal ureter

Block	Sect. Site	PCs
1	M	2
1	U	2

Part 6: Right distal ureter

Block	Sect. Site	PCs
1	M	2
1	U	2

Intraoperative Consultation:

1. Urethral margin (fs): Benign
Permanent diagnosis: Same.

Source: NCI Genomic Data Commons file 953c3e7d-9dd0-46e1-954a-6db07c49cd89 (TCGA-DK-A3IU.7BDC2B9E-DB52-4D92-9712-CBE3B6A67706.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).